Somatic mutation profile of tumor specimen TCGA-A6-6650-01B (aliquot TCGA-A6-6650-01B-02D-A270-10) from TCGA case TCGA-A6-6650, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.9 years (25,516 days).
Specimen TCGA-A6-6650-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 997cb67e-a4aa-4a5f-917a-1d60441c80e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6650-10A (Blood Derived Normal), aliquot TCGA-A6-6650-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b14f983-e177-4b1e-8d1e-cd092c395e93

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 75, Silent 29, Frame Shift Del 6, Frame Shift Ins 2, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPOX | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374394802, CM970392, COSV51637936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GFM1 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs375512235, COSV51834894; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC10 | c.3268C>T p.R1090W (on ENST00000372530 / NM_001198934.2; = p.R1062W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187313814; called by muse, mutect2, varscan2
- ACTL9 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555753423, COSV61006777; called by muse, varscan2
- APC | c.4224_4225insATGAA p.P1409Mfs*8 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | catalogued as COSV57368171; called by mutect2, varscan2
- ARMC4 | c.2804A>C p.N935T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV59463724; called by muse, mutect2
- B3GALT5 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs766898271, COSV58200039; called by muse, mutect2, varscan2
- BCHE | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100012005, COSV52253121; called by muse, mutect2
- CCDC157 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841389; called by muse, mutect2
- CDC42BPG | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61348659; called by muse, mutect2, varscan2
- CDHR3 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs923289068, COSV58420327; called by muse, mutect2, varscan2
- CNTNAP5 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1455891898, COSV70476949; called by muse, mutect2, varscan2
- COL12A1 | c.8527T>G p.F2843V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.848); catalogued as COSV59403952; called by muse, mutect2, varscan2
- CRMP1 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs187171314, COSV61478219; called by muse, mutect2, varscan2
- DAPK1 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV63790431; called by muse, mutect2, varscan2
- DDIT4L | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1445763095, COSV56767887; called by muse, mutect2
- DNAH10 | c.2653G>A p.D885N (on ENST00000409039; = p.D824N on NM_207437.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.739); catalogued as rs776514851, COSV68989002, COSV68991354; called by muse, mutect2, varscan2
- ESYT2 | c.1113T>G p.S371R (on ENST00000613624; = p.S295R on NM_020728.3) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.667); catalogued as COSV51754987; called by muse, mutect2, varscan2
- FARS2 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as COSV51172611; called by muse, mutect2, varscan2
- FBN1 | c.6302C>T p.T2101M | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs200816828, CM020692; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV64309337; called by muse, mutect2
- HECW1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs751728485, COSV67826141; called by muse, mutect2, varscan2
- HSPA2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV55970870; called by muse, mutect2, varscan2
- IFFO1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs867248785, COSV59112944; called by muse, mutect2, varscan2
- IL31RA | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs779967750, COSV51683967; called by muse, mutect2, varscan2
- KCNAB2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1242648822, COSV51238372; called by muse, mutect2, varscan2
- KRT79 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761058456, COSV57941735; called by muse, mutect2, varscan2
- LARP4 | c.467C>G p.T156R | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53325729; called by muse, mutect2, varscan2
- LAS1L | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV56707541; called by muse, mutect2, varscan2
- MAGEB6 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs200923993, COSV66872390, COSV66872804; called by muse, mutect2, varscan2
- MID1IP1 | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61230980; called by muse, mutect2, varscan2
- MRAP2 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57634026; called by muse, mutect2, varscan2
- MUC16 | c.7694C>T p.T2565M | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs776081952, COSV67483278; called by muse, mutect2, varscan2
- NDUFS8 | c.58+2T>G p.X20_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV50290263; called by muse, mutect2, varscan2
- NEK10 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV58287727; called by muse, varscan2
- NIFK | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53535505; called by muse, mutect2, varscan2
- NRCAM | c.3034C>T p.R1012W (on ENST00000379028 / NM_001371124.1; = p.R996W on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs200175819; called by mutect2, varscan2
- NRG3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV64577351; called by muse, mutect2, varscan2
- NRXN2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs753732547, COSV55459296; called by muse, mutect2, varscan2
- OR2A5 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV68739009; called by muse, mutect2, varscan2
- PBX2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs774240386, COSV66682903; called by muse, mutect2
- PCDH11X | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs758221295, COSV53492818; called by muse, varscan2
- PCDH17 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64977399; called by muse, mutect2
- PCDH9 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs375314712, COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PRDM9 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV57010925, COSV99690866; called by muse, mutect2, varscan2
- PRKAG1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60292552, COSV60294208; called by muse, mutect2, varscan2
- RAN | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54563341; called by muse, varscan2
- RANBP6 | c.1011_1013del p.E337del | In Frame Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs1252206036; called by pindel, varscan2
- RBM10 | c.2261C>A p.T754N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61311001; called by muse, mutect2, varscan2
- RELN | c.8683C>T p.R2895C | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs573510714, COSV58997874, COSV59004413; called by muse, mutect2, varscan2
- RNFT1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 164/356 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV59870283; called by muse, mutect2, varscan2
- RP1L1 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs760657386; called by muse, mutect2, varscan2
- SCARF2 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1221991531; called by muse, mutect2, varscan2
- SEMA4F | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs143403780; called by muse, mutect2
- SEPTIN9 | c.287C>T p.S96L (on ENST00000427177 / NM_001113491.2; = p.S78L on NM_006640.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs1309991827, COSV61208599, COSV61209202; called by muse, mutect2, varscan2
- SIX2 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV57391813; called by muse, mutect2, varscan2
- SLC25A46 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63507007; called by muse, mutect2
- SORBS2 | c.53C>T p.S18L (on ENST00000284776 / NM_021069.5; = p.S64L on NM_003603.6) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV53010533; called by muse, mutect2
- SPATA19 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs748936093, COSV104406994, COSV54484506; called by muse, mutect2
- TCEAL1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV65461206; called by muse, mutect2, varscan2
- TTLL3 | c.2478C>A p.D826E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1042203779, COSV59615320; called by muse, mutect2
- TUBA3C | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs544706766, COSV67139776; called by muse, mutect2, varscan2
- UIMC1 | c.1847del p.K616Rfs*59 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs750118715; called by mutect2, pindel, varscan2
- USP9X | c.5553G>T p.E1851D | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61073454; called by muse, mutect2, varscan2
- ZFP36L2 | c.1483T>A p.*495Rext*81 | Nonstop Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV56698705; called by muse, mutect2, varscan2
- ZMYM2 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs1371106211; called by muse, mutect2, varscan2
- ZNF536 | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.117); catalogued as COSV62831077, COSV62837016; called by muse, mutect2
- ZNF835 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs777423402; called by muse, mutect2
- ARHGEF9 | c.1240dup p.I414Nfs*18 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- DNAI4 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELMO1 | c.1053_1068del p.M351Ifs*63 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- ETV1 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HMCN1 | c.15908G>T p.G5303V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSPA6 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- IL1RL2 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- KPNA3 | c.1265T>A p.V422E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, varscan2
- MIA3 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.326); called by muse, mutect2
- MMP2 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- OR5H14 | c.600del p.F200Lfs*12 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel, varscan2
- OSMR | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RTL5 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- SLC30A8 | c.190del p.A64Rfs*22 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- STON2 | c.1233C>A p.S411R (on ENST00000649389 / NM_001366849.2; = p.S354R on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2
- TBC1D32 | c.3009_3010del p.L1005Ffs*9 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- USP9X | c.5554C>T p.Q1852* | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | called by muse, varscan2
- WNK1 | c.849_852del p.F283Lfs*8 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- ACTB | c.661C>T p.L221= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV59320398; called by muse, mutect2, varscan2
- ANKMY1 | c.2751G>A p.K917= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56039027; called by muse, mutect2
- ARMC9 | c.1572A>G p.G524= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- BBS7 | c.864C>T p.S288= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs142376157; called by muse, mutect2, varscan2
- CACNA1F | c.4002C>T p.I1334= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV59906311; called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs17879825; called by muse, varscan2
- CRIP2 | c.480G>A p.L160= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.957C>A p.A319= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV65789460; called by muse, mutect2, varscan2
- DNAH1 | c.1356C>A p.I452= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV70233748; called by muse, mutect2, varscan2
- DNER | c.1203C>T p.C401= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- HLA-DOA | c.381G>A p.Q127= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV57715305; called by muse, mutect2, varscan2
- KCNH2 | c.2292G>A p.P764= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs766291953, COSV51218572; called by muse, mutect2, varscan2
- LONRF3 | c.1401C>T p.C467= (on ENST00000371628 / NM_001031855.3; = p.C426= on NM_024778.5) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1471680397, COSV59155627; called by muse, mutect2, varscan2
- LRWD1 | c.105C>T p.S35= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs781734393, COSV52961679; called by muse, mutect2, varscan2
- MAP4K1 | c.1390C>A p.R464= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV67712269; called by muse, mutect2, varscan2
- MEI1 | c.276C>T p.I92= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV55905949; called by muse, mutect2, varscan2
- MMGT1 | c.75G>A p.A25= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV60003978; called by muse, mutect2
- MTRR | c.1509G>T p.L503= (on ENST00000264668; = p.L476= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52946007, COSV52947548; called by muse, mutect2, varscan2
- PDLIM1 | c.135T>C p.C45= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV61474668; called by muse, mutect2, varscan2
- PHF8 | c.1707G>T p.L569= (on ENST00000357988 / NM_001184896.1; = p.L533= on NM_015107.3) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57686168; called by muse, mutect2, varscan2
- RBCK1 | c.225G>T p.V75= (on ENST00000356286 / NM_031229.4; = p.V33= on NM_006462.6) | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV62292985; called by muse, mutect2, varscan2
- ROR1 | c.2577C>G p.A859= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV64291367; called by muse, mutect2, varscan2
- SCN7A | c.2778C>T p.T926= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV69273742; called by muse, mutect2, varscan2
- SCUBE3 | c.897C>T p.F299= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs757346890, COSV51454766; called by muse, mutect2, varscan2
- SHROOM2 | c.2028C>T p.L676= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1340502942, COSV66609474; called by muse, mutect2, varscan2
- SIK3 | c.3543G>A p.L1181= (on ENST00000445177 / NM_001366686.2; = p.L1139= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV52620887; called by muse, mutect2, varscan2
- UBR3 | c.5490C>T p.R1830= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV55856940; called by muse, mutect2, varscan2
- XPO4 | c.2160A>T p.V720= | Silent (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- ZNF28 | c.1212T>A p.I404= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV60424690; called by muse, mutect2, varscan2
